Surgical pathology report (de-identified scan), TCGA case TCGA-19-2624, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-2624-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT**FINAL DIAGNOSIS**

A-C. LEFT TEMPORAL LOBE OF BRAIN, LESION, BIOPSY AND REMOVAL:
-- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

Note: Specimen "A" demonstrates infiltrating anaplastic astrocytoma. Both specimens labeled gross tumor and enhancing white matter demonstrate glioblastoma multiforme within the majority of sections examined.

Electronically Signed Out By

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consult Diagnosis

A: Touch Imprint and Microscopic: Anaplastic Astrocytoma.

Clinical History:

left temporal tumor

Specimens Submitted As:

A: LEFT TEMPORAL LESION
B: GROSS TUMOR
C: ENHANCING WHITE MATTER

Gross Description:

A: Received fresh labeled with the patient's name, hospital number and "left temporal lesion" is one tan-pink soft tissue fragment, 0.5 x 0.4 x 0.2 cm. The specimen is bisected and a portion of the specimen is frozen for intraoperative diagnosis. Touch preparations are also prepared. The remainder of the specimen is entirely submitted in a single cassette.

B: Received fresh, post fixed in formalin, labeled with the patient's name and number, and "A", are multiple irregular, opaque white to pink tan, soft, cerebriform tissue fragments measuring in aggregate 6.0 x 3.5 x 2.3 cm. Submitted entirely in 11 cassettes.

C: Received fresh, post fixed in formalin, labeled with the patient's name and number, and "B", are multiple irregular, opaque white to pink tan, soft, cerebriform tissue fragments measuring in aggregate 4.2 x 3.1 x 1.5 cm. Submitted entirely in eight cassettes.

Summary of Cassettes:

Specimen	Label	Site
A	1	frozen section, one half of specimen
	2	remainder of specimen entirely submitted

Source: NCI Genomic Data Commons file 8b885ab3-b9ff-4df1-ba42-bd6c26f07cdb (TCGA-19-2624.C100BCAF-5C75-464E-97B5-9FF575796709.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).